Somatic mutation profile of tumor specimen TCGA-XU-AAY0-01A (aliquot TCGA-XU-AAY0-01A-11D-A428-09) from TCGA case TCGA-XU-AAY0, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type AB, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 62.0 years (22,645 days).
Specimen TCGA-XU-AAY0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d5641844-3a5a-46a8-8674-9b9a36abb27b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XU-AAY0-10A (Blood Derived Normal), aliquot TCGA-XU-AAY0-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0bd1947f-d7e4-45fa-aa08-c3eba4a98e3a

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 28/305 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- JCAD | c.1685A>G p.Q562R | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs780101325, COSV64758463; called by muse, mutect2, varscan2
- NRXN1 | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs746974723, COSV100457590; called by muse, mutect2, varscan2
- DNMT3B | c.704G>A p.G235D | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); called by muse, mutect2
- HTATSF1 | c.395A>G p.N132S | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- POLR3B | c.966+1G>T p.X322_splice | Splice Site (SNP) | VAF 4/31 reads (13%) | called by muse, varscan2
- STRADB | c.538T>A p.C180S | Missense Mutation (SNP) | VAF 3/53 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.102); called by muse, mutect2
- CRYBG2 | c.1368C>A p.L456= | Silent (SNP) | VAF 4/31 reads (13%) | called by mutect2, varscan2
- TMX4 | c.579C>T p.V193= | Silent (SNP) | VAF 3/49 reads (6%) | catalogued as rs1244448181; called by muse, mutect2
